Gene-level copy-number profile of tumor specimen TCGA-CS-6188-01A from TCGA case TCGA-CS-6188, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 48.5 years (17,729 days).
Specimen TCGA-CS-6188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.4e7d8475-0fd7-4d38-8ca0-9bd1585cabd7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CS-6188-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dcfcbe62-7602-4744-9359-8827e129d10a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 5,532; copy number 2: 48,606; copy number 3: 5,629; copy number 32: 4; copy number 36: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CS-6188-01A-11D-1892-01): tumor purity 0.68, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,830,308, 14 genes (within-gene range 0–1): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1.
- chr9:21,967,752–22,824,213, 10 genes (within-gene range 0–1): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:53,490,148–54,938,184, 23 genes, copy number 36: RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1.
- chr7:55,179,750–55,260,256, 4 genes, copy number 32: EGFR-AS1, ELDR, AC073324.1, CALM1P2.

Autosomal genes at a single copy (total copy number 1): 3,152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
